Gene-level copy-number profile of tumor specimen C3N-03487-02 from CPTAC case C3N-03487, project CPTAC-3 (Gum — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,702 days).
Specimen C3N-03487-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e094b1c3-9bd6-4b49-aa67-9d035b09062b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03487-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/be19ce6b-ec5b-47df-97e6-962de629dcc9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 4,581; copy number 2: 49,305; copy number 3: 4,273; copy number 4: 26; copy number 5: 108.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,990,496–22,552,156, 106 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 108 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:19,215,615–19,336,715, 1 gene, copy number 5 (within-gene range 4–5): EPN2.
- chr17:19,296,596–21,092,351, 107 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
